Somatic mutation profile of tumor specimen TCGA-39-5019-01A (aliquot TCGA-39-5019-01A-01D-1817-08) from TCGA case TCGA-39-5019, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.5 years (25,756 days).
Specimen TCGA-39-5019-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d51ff30c-262f-406c-864c-33779dbd6bc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5019-11A (Solid Tissue Normal), aliquot TCGA-39-5019-11A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f8674fd-5fd5-4495-bd72-ee51bdc0f71e

The open-access MAF lists 194 somatic variants for this specimen: 143 protein-altering or splice-affecting, 41 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 41, Nonsense Mutation 10, Frame Shift Del 6, RNA 5, Intron 5, Splice Region 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPAST | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1060502227, CD052507, CM000436, CM101456, COSV59514516; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | hotspot (GDC flag); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2, varscan2
- ABI3BP | c.763C>G p.H255D | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52536526; called by muse, mutect2, varscan2
- ACOT2 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as COSV53150367; called by muse, mutect2, varscan2
- ACTR8 | c.996C>G p.C332W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51636526; called by muse, mutect2, varscan2
- ADAM18 | c.1327-2A>T p.X443_splice | Splice Site (SNP) | VAF 78/120 reads (65%) | catalogued as COSV55847593; called by muse, mutect2, varscan2
- ADAMTS16 | c.2041C>A p.L681I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56989911; called by muse, mutect2
- AKAP13 | c.3277G>T p.G1093W | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.145); catalogued as COSV63457411; called by muse, mutect2, varscan2
- ANO8 | c.3329C>A p.S1110* | Nonsense Mutation (SNP) | VAF 14/250 reads (6%) | catalogued as COSV50177887; called by muse, mutect2
- AP4M1 | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV57996494; called by muse, mutect2, varscan2
- ASB12 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62856937; called by muse, mutect2, varscan2
- ATP6V0D2 | c.210T>G p.I70M | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53415014; called by muse, mutect2, varscan2
- AVPR2 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61686229; called by muse, mutect2, varscan2
- BCORL1 | c.1460A>C p.D487A | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV54396541; called by muse, mutect2
- BMP3 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV51083399, COSV51084488; called by muse, mutect2, varscan2
- BMPER | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV51818743; called by muse, mutect2, varscan2
- CAVIN3 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as rs747325306, COSV58268893; called by muse, mutect2, varscan2
- CD37 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60543942, COSV60544348; called by muse, mutect2, varscan2
- CDHR2 | c.3656C>A p.A1219D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV56138865; called by muse, mutect2, varscan2
- CENPI | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 11/334 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV54502573; called by muse, mutect2
- CEP350 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV62485879; called by muse, mutect2, varscan2
- CFAP61 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs750210901, COSV55629755, COSV55645473; called by muse, mutect2, varscan2
- CHD4 | c.3280G>C p.E1094Q (on ENST00000357008 / NM_001363606.2; = p.E1107Q on NM_001273.5) | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV58901321; called by muse, mutect2, varscan2
- COL6A5 | c.7028C>T p.P2343L (on ENST00000312481; = p.P2339L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV55202065; called by muse, mutect2, varscan2
- CR1 | c.303T>C p.R101= | Splice Region (SNP) | VAF 13/98 reads (13%) | catalogued as rs777178887, COSV65458262; called by muse, mutect2, varscan2
- CRYBG1 | c.3814A>G p.T1272A | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV64812192; called by muse, mutect2, varscan2
- CWH43 | c.2083C>G p.P695A | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56938980, COSV99893442; called by muse, mutect2
- CYP4F11 | c.857T>C p.F286S | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV56127021; called by muse, mutect2, varscan2
- CYTH3 | c.413A>G p.H138R | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV63438799; called by muse, mutect2, varscan2
- DAW1 | c.769T>A p.L257I | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV59365433; called by muse, mutect2, varscan2
- DCAF15 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs1340192081, COSV54329962; called by muse, mutect2, varscan2
- DEFB118 | c.292A>C p.S98R | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs1379363893, COSV53620335; called by muse, mutect2, varscan2
- DEFB118 | c.293G>T p.S98I | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV53620345; called by muse, mutect2, varscan2
- DLG2 | c.401C>A p.P134Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV54644952, COSV54680601; called by muse, mutect2, varscan2
- DLG2 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV54644993; called by muse, mutect2, varscan2
- DLGAP1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as rs372048186; called by muse, mutect2, varscan2
- DST | c.65A>T p.Y22F | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.99); catalogued as COSV100421872, COSV100422124; called by muse, mutect2, varscan2
- EEF2K | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 22/124 reads (18%) | catalogued as COSV53782007; called by muse, mutect2, varscan2
- EFCAB5 | c.4138C>T p.R1380C | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs754404201, COSV57926755; called by muse, mutect2, varscan2
- EGFLAM | c.294G>A p.E98= | Splice Region (SNP) | VAF 24/122 reads (20%) | catalogued as rs1376956895, COSV59302609; called by muse, mutect2, varscan2
- EIF3C | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 184/1159 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs780196959, COSV59060345; called by muse, mutect2, varscan2
- EML2 | c.1066A>C p.T356P | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV55597898, COSV55599660; called by muse, mutect2, varscan2
- ERF | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55896012; called by muse, mutect2, varscan2
- EXD2 | c.1300G>A p.V434M (on ENST00000312994 / NM_001193362.1; = p.V309M on NM_018199.3) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs775794862, COSV57279524; called by muse, mutect2, varscan2
- FAM71A | c.537G>T p.E179D | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54235717; called by muse, mutect2
- FGD6 | c.2354A>G p.D785G | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV59693347; called by muse, mutect2, varscan2
- FGG | c.501C>A p.D167E | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV60195387; called by muse, mutect2, varscan2
- FN1 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV60553012; called by muse, mutect2
- FNDC1 | c.1939T>C p.S647P | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV51938026; called by muse, mutect2, varscan2
- FZD10 | c.1627A>T p.S543C | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV57473625; called by muse, mutect2, varscan2
- GABRQ | c.1576G>T p.G526C | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782374203, COSV64782071; called by muse, mutect2, varscan2
- GREB1 | c.3995G>T p.R1332L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV52187192; called by muse, mutect2, varscan2
- GRK6 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.063); catalogued as COSV62682635, COSV62683697; called by muse, mutect2
- GTDC1 | c.694C>G p.R232G | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV53987909, COSV53994942; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1987G>T p.G663W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV57132295; called by muse, mutect2, varscan2
- IFNG | c.194G>C p.R65T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV57491284, COSV57491711; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 87/412 reads (21%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.784); catalogued as rs373204588; called by muse, mutect2, varscan2
- IMMT | c.1512A>T p.E504D | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as rs747451990, COSV54486988; called by muse, mutect2, varscan2
- JADE2 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs368664750; called by muse, mutect2, varscan2
- KCTD21 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV60741129; called by muse, mutect2, varscan2
- KIF16B | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.876); catalogued as COSV61702485, COSV61706284; called by muse, mutect2
- LIPG | c.1105T>C p.Y369H | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.038); catalogued as COSV54296293; called by muse, mutect2, varscan2
- MCM8 | c.1366C>G p.P456A | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54513803; called by muse, mutect2, varscan2
- MED23 | c.162G>A p.E54= | Splice Region (SNP) | VAF 16/78 reads (21%) | catalogued as COSV63432611; called by muse, mutect2, varscan2
- MTUS2 | c.680C>A p.A227E | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.124); catalogued as COSV70916809; called by muse, mutect2, varscan2
- MYH1 | c.4582C>A p.H1528N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV56848573; called by muse, mutect2, varscan2
- MYH6 | c.5002G>T p.D1668Y | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62450523; called by muse, mutect2, varscan2
- MYO16 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51790733, COSV51794628; called by muse, mutect2, varscan2
- NIPSNAP1 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311706190, COSV53342133; called by muse, mutect2, varscan2
- NISCH | c.4109C>G p.P1370R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58736279, COSV58744235; called by muse, mutect2, varscan2
- NLRP13 | c.2330C>A p.A777D | Missense Mutation (SNP) | VAF 46/223 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV61621737; called by muse, mutect2, varscan2
- OR2L2 | c.169C>G p.P57A | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63552930; called by muse, mutect2, varscan2
- OR5D16 | c.773T>C p.L258P | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65721992; called by muse, mutect2
- OR5D18 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs142474714, COSV61736233; called by muse, mutect2, varscan2
- OR6K2 | c.355T>A p.F119I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV62743500; called by muse, mutect2, varscan2
- OR8J3 | c.746C>A p.T249K | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV56880240, COSV56880864, COSV56884935; called by muse, mutect2
- P2RX3 | c.679C>A p.Q227K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54442684; called by muse, mutect2, varscan2
- PADI2 | c.399C>A p.N133K | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.89); catalogued as COSV64945876; called by muse, mutect2, varscan2
- PARD3B | c.522G>T p.L174F | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV62511695; called by muse, mutect2, varscan2
- PARD3B | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | catalogued as COSV100592123, COSV62511705; called by muse, mutect2, varscan2
- PCDHB10 | c.2215G>T p.V739L | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.021); catalogued as COSV53378846; called by muse, mutect2
- PCDHGA10 | c.523C>A p.Q175K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.029); catalogued as COSV53949394; called by muse, mutect2, varscan2
- PCLO | c.7729A>G p.T2577A | Missense Mutation (SNP) | VAF 97/288 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV61635608; called by muse, mutect2, varscan2
- PELI3 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV57855929, COSV57856849; called by muse, mutect2, varscan2
- PGS1 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53145286; called by muse, mutect2
- PIAS2 | c.1060A>T p.T354S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.05); catalogued as COSV61343320; called by muse, mutect2, varscan2
- PLCB4 | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.979); catalogued as COSV53801986; called by muse, mutect2, varscan2
- PLCH1 | c.2396T>A p.V799E (on ENST00000340059 / NM_001130960.2; = p.V811E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58197451; called by muse, mutect2, varscan2
- PLCXD3 | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs764548699, COSV60608912; called by muse, mutect2
- PLPPR5 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV54173185; called by muse, mutect2
- PLXNA4 | c.3776C>T p.A1259V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV58126470; called by muse, mutect2, varscan2
- PMPCB | c.327+1G>T p.X109_splice | Splice Site (SNP) | VAF 5/57 reads (9%) | catalogued as COSV50786122; called by muse, mutect2
- PPP4R3B | c.1917G>C p.L639F (on ENST00000616407 / NM_001122964.3; = p.L554F on NM_020463.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV55404689; called by muse, mutect2
- PRR23B | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as COSV61493882; called by muse, mutect2, varscan2
- PSMC2 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53007478; called by muse, mutect2, varscan2
- PTPRN2 | c.1288C>A p.H430N | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV101233792, COSV67038345; called by muse, mutect2
- R3HDML | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV53836019; called by muse, mutect2, varscan2
- RB1CC1 | c.778A>T p.K260* | Nonsense Mutation (SNP) | VAF 142/255 reads (56%) | catalogued as COSV50249337; called by muse, mutect2, varscan2
- RIF1 | c.988A>G p.R330G | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54614834; called by muse, mutect2, varscan2
- RTN1 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV50724321; called by muse, mutect2, varscan2
- RXFP3 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV57505627; called by muse, mutect2, varscan2
- SAMHD1 | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV53429690; called by muse, mutect2
- SELE | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV60975489; called by muse, mutect2, varscan2
- SLCO4C1 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as COSV60515783; called by muse, mutect2, varscan2
- SMPDL3A | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.279); catalogued as COSV63755387; called by muse, mutect2, varscan2
- SNX17 | c.1366G>T p.V456F | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52007829; called by muse, mutect2, varscan2
- SOCS5 | c.1286G>T p.R429L | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV60603916, COSV60604974; called by muse, mutect2, varscan2
- SPAG6 | c.786C>A p.D262E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV57620472; called by muse, mutect2, varscan2
- SPHKAP | c.4244A>T p.N1415I | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV60879268; called by muse, mutect2, varscan2
- STKLD1 | c.332A>T p.N111I | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV64312768; called by mutect2, varscan2
- STYXL2 | c.3159G>T p.E1053D | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV54805239; called by muse, mutect2, varscan2
- SUGCT | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59331069, COSV59351806; called by muse, varscan2
- SYCP1 | c.891T>A p.N297K | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.895); catalogued as rs934630546, COSV65697498; called by muse, mutect2, varscan2
- SYNE1 | c.19189G>A p.V6397I (on ENST00000367255 / NM_182961.4; = p.V6326I on NM_033071.3) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1279994576, COSV54984018; called by muse, mutect2, varscan2
- TAF1L | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV54261953; called by muse, mutect2, varscan2
- TARBP1 | c.3386G>T p.G1129V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV50184679; called by muse, mutect2, varscan2
- THADA | c.4586C>T p.A1529V | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV57683749; called by muse, mutect2, varscan2
- TMEM63B | c.1406A>T p.Y469F | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV52478944; called by muse, mutect2, varscan2
- TNS2 | c.3061C>T p.R1021* (on ENST00000314250 / NM_170754.4; = p.R1031* on NM_015319.2) | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs1396407440, COSV56853893; called by muse, mutect2, varscan2
- TTN | c.100055C>A p.T33352K (on ENST00000591111; = p.T25928K on NM_003319.4) | Missense Mutation (SNP) | VAF 36/100 reads (36%) | PolyPhen benign (0.119); catalogued as rs368945564, COSV60067083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.88154A>G p.K29385R (on ENST00000591111; = p.K21961R on NM_003319.4) | Missense Mutation (SNP) | VAF 32/248 reads (13%) | PolyPhen benign (0.024); catalogued as COSV60067126; called by muse, mutect2, varscan2
- TTN | c.63362T>A p.L21121Q (on ENST00000591111; = p.L13697Q on NM_003319.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | PolyPhen probably damaging (0.999); catalogued as COSV60067168; called by muse, mutect2, varscan2
- TTN | c.59182C>T p.P19728S (on ENST00000591111; = p.P12304S on NM_003319.4) | Missense Mutation (SNP) | VAF 38/114 reads (33%) | PolyPhen probably damaging (0.998); catalogued as rs1388682620, COSV60067214; called by muse, mutect2, varscan2
- TUBA3C | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.269); catalogued as COSV67139298; called by muse, mutect2
- UBE3C | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as rs1563040735, COSV61953243; called by muse, mutect2, varscan2
- UNC5D | c.2828C>A p.A943D | Missense Mutation (SNP) | VAF 72/106 reads (68%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV54794888; called by muse, mutect2, varscan2
- USH1C | c.1078A>G p.M360V | Missense Mutation (SNP) | VAF 107/258 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs756115246, COSV50018192; called by muse, mutect2, varscan2
- USP10 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1189501777, COSV54748925; called by muse, mutect2
- VN1R1 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.413); catalogued as rs1335608709, COSV58091062, COSV58091392; called by muse, mutect2
- VWA5A | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs367908177; called by muse, mutect2, varscan2
- XRRA1 | c.307T>C p.S103P | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58497894; called by muse, mutect2, varscan2
- ZFP36L2 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.059); catalogued as COSV56697423, COSV56700013; called by muse, mutect2
- ZMIZ1 | c.2892C>A p.H964Q | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.79); catalogued as rs770316858, COSV57895642; called by muse, mutect2, varscan2
- IGKV1-27 | c.44T>A p.L15H | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGKV1D-13 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.246); called by mutect2, varscan2
- ITPRIPL1 | c.731del p.P244Hfs*10 (on ENST00000439118 / NM_001008949.3; = p.P252Hfs*10 on NM_178495.6) | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- KCNN3 | c.2180del p.S727Tfs*22 (on ENST00000618040 / NM_001204087.1; = p.S712Tfs*22 on NM_002249.6) | Frame Shift Del (DEL) | VAF 79/247 reads (32%) | called by mutect2, pindel, varscan2
- NBAS | c.4225del p.W1409Gfs*7 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- PTPRH | c.1774del p.H592Tfs*61 | Frame Shift Del (DEL) | VAF 19/146 reads (13%) | called by mutect2, pindel, varscan2
- SELP | c.1988del p.G663Vfs*17 | Frame Shift Del (DEL) | VAF 93/287 reads (32%) | called by mutect2, pindel, varscan2
- TAS2R5 | c.882del p.R295Dfs*34 | Frame Shift Del (DEL) | VAF 81/302 reads (27%) | called by mutect2, pindel, varscan2
- TRAV8-7 | c.115A>C p.K39Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- WBP1 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.212); called by muse, mutect2
- ABCA10 | c.2997C>T p.Y999= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV52222243; called by muse, mutect2, varscan2
- ABCC9 | c.726T>A p.P242= | Silent (SNP) | VAF 11/130 reads (8%) | catalogued as COSV53971818; called by muse, mutect2
- ADAMTS12 | c.2766G>T p.P922= | Silent (SNP) | VAF 19/127 reads (15%) | catalogued as COSV61262850, COSV61263240; called by muse, mutect2, varscan2
- ADAMTS3 | c.1032C>G p.L344= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV54391697; called by muse, mutect2, varscan2
- ARID5A | c.1665C>T p.P555= | Silent (SNP) | VAF 58/178 reads (33%) | catalogued as COSV62591155; called by muse, mutect2, varscan2
- CCDC171 | c.2655C>T p.D885= | Silent (SNP) | VAF 23/224 reads (10%) | catalogued as rs779856240, COSV52636190; called by muse, mutect2, varscan2
- CFAP54 | c.6360C>A p.V2120= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs1423474864, COSV61572252; called by muse, mutect2, varscan2
- COL5A1 | c.1590C>A p.G530= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV65668994; called by muse, mutect2, varscan2
- CTNNA3 | c.768A>C p.S256= | Silent (SNP) | VAF 65/178 reads (37%) | catalogued as COSV65583376; called by muse, mutect2, varscan2
- DNAH10 | c.4125C>T p.G1375= (on ENST00000409039; = p.G1314= on NM_207437.3) | Silent (SNP) | VAF 62/148 reads (42%) | catalogued as COSV68993918; called by muse, mutect2, varscan2
- DNAH17 | c.10884C>T p.S3628= | Silent (SNP) | VAF 21/38 reads (55%) | catalogued as rs138142447; called by muse, mutect2, varscan2
- DYNC1I1 | c.1737C>A p.S579= | Silent (SNP) | VAF 28/240 reads (12%) | catalogued as COSV61460909; called by muse, mutect2, varscan2
- EXOC4 | c.450T>C p.Y150= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV54098612; called by muse, mutect2, varscan2
- FIGN | c.1908A>T p.I636= | Silent (SNP) | VAF 10/130 reads (8%) | catalogued as rs921486372, COSV60766724; called by muse, mutect2
- HCN1 | c.2010G>T p.A670= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs755532252, COSV57496207, COSV57511213; called by muse, mutect2, varscan2
- HOXC5 | c.96G>A p.E32= | Silent (SNP) | VAF 54/115 reads (47%) | catalogued as rs1194310286, COSV54536900; called by muse, varscan2
- HUNK | c.1872C>T p.H624= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs376197217, COSV54226079; called by muse, mutect2, varscan2
- IL1R2 | c.1060C>T p.L354= | Silent (SNP) | VAF 60/140 reads (43%) | catalogued as COSV60207186; called by muse, mutect2, varscan2
- LGALS13 | c.351G>A p.P117= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV55679959; called by muse, mutect2, varscan2
- MYH14 | c.5790G>T p.S1930= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as COSV51818064; called by muse, mutect2, varscan2
- MYOC | c.480G>A p.R160= | Silent (SNP) | VAF 35/423 reads (8%) | catalogued as COSV50674888; called by muse, mutect2
- NSF | c.1833C>T p.Y611= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1325866759, COSV56574927; called by muse, mutect2, varscan2
- OR2T1 | c.741G>A p.V247= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as rs1372285302, COSV63541939; called by muse, mutect2, varscan2
- OR4M1 | c.927G>A p.L309= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV60061394, COSV60063199; called by muse, mutect2
- OR6K2 | c.550C>T p.L184= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs760709059, COSV62743496; called by muse, mutect2, varscan2
- PBLD | c.357C>A p.I119= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as COSV53265981, COSV53266026; called by muse, mutect2, varscan2
- PRB4 | c.111A>G p.E37= | Silent (SNP) | VAF 48/472 reads (10%) | catalogued as COSV54396955; called by muse, varscan2
- PSMD12 | c.228G>A p.E76= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as rs551667831, COSV62065735; called by muse, mutect2
- PTPRC | c.3363A>G p.Q1121= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1164152225, COSV61411885; called by muse, mutect2, varscan2
- SLC8A1 | c.769C>T p.L257= | Silent (SNP) | VAF 14/158 reads (9%) | catalogued as rs1369301727, COSV60480898; called by muse, mutect2
- SRP72 | c.1512A>G p.K504= | Silent (SNP) | VAF 42/173 reads (24%) | catalogued as COSV61377801; called by muse, mutect2, varscan2
- STK32B | c.513G>T p.V171= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV51487725; called by muse, mutect2, varscan2
- TENM1 | c.7854G>A p.R2618= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV64432078; called by muse, mutect2, varscan2
- TMEM151A | c.738C>T p.N246= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1022098007, COSV59173802; called by muse, varscan2
- TMEM18 | c.345G>A p.K115= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV55244002; called by muse, mutect2, varscan2
- TRIM28 | c.2181C>T p.S727= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs763622570, COSV53400286; called by muse, mutect2, varscan2
- UBE2N | c.261T>C p.C87= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV58867733; called by muse, mutect2, varscan2
- ZC3H3 | c.2085G>A p.E695= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV52789088; called by muse, mutect2, varscan2
- ZDHHC8 | c.747G>T p.A249= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100273064, COSV57708903; called by muse, mutect2, varscan2
- ZIC1 | c.372G>A p.S124= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV51553636, COSV99291455; called by muse, mutect2, varscan2
- ZNF831 | c.3003G>A p.A1001= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as rs765856551, COSV64040322; called by muse, mutect2, varscan2
- AC073310.1 | n.875T>A | RNA (SNP) | VAF 58/214 reads (27%) | catalogued as rs1399794662; called by muse, mutect2, varscan2
- ACSM1 | c.1197+204G>T | Intron (SNP) | VAF 34/175 reads (19%) | catalogued as COSV99533125; called by muse, mutect2, varscan2
- ARHGAP6 | c.589-35769G>T | Intron (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100498431; called by muse, mutect2, varscan2
- DCHS2 | n.3680G>A | RNA (SNP) | VAF 8/27 reads (30%) | catalogued as COSV61771847, COSV61772202; called by muse, mutect2, varscan2
- DNM1P46 | n.1003C>T | RNA (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2
- IGKV1-13 | n.267C>A | RNA (SNP) | VAF 34/294 reads (12%) | catalogued as rs1286505013; called by muse, mutect2, varscan2
- MCM7 | c.1848+137C>T | Intron (SNP) | VAF 11/39 reads (28%) | catalogued as COSV57996491; called by muse, mutect2, varscan2
- PNCK | c.539-30T>C | Intron (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100562368; called by muse, mutect2, varscan2
- PTHLH | c.-23+141A>G | Intron (SNP) | VAF 98/230 reads (43%) | catalogued as rs368488330, COSV99570975; called by muse, mutect2, varscan2
- SNORD108 | n.25C>G | RNA (SNP) | VAF 36/124 reads (29%) | called by muse, mutect2, varscan2
